Surgical pathology report (de-identified scan), TCGA case TCGA-WZ-A7V5, project TCGA-TGCT (Testicular Germ Cell Tumors), tissue source site  International Genomics Consortium, specimen TCGA-WZ-A7V5-01A (Primary Tumor).

[page 1 of 2]
Results

Specimen Information

Collection Date and Time

Component Results

SURGICAL PANEL:

SURGICAL PATHOLOGY REPORT

Final Report

DIAGNOSIS

RIGHT TESTICLE AND SPERMATIC CORD, ORCHIECTOMY: Seminoma, measuring 4.9 cm in greatest dimension, angiolymphatic invasion is present, tumor involves tunica albuginea and rete testis, surgical margins negative for tumor

*****2010 TESTIS CANCER STAGING PARAMETERS*****

Case number: Patient name:

Final TNM: pT2NXM0

2010 stage: I

MACROSCOPIC

SPECIMEN TYPE

Radical Orchiectomy

TUMOR LATERALITY

Right

TUMOR SIZE

4.9 X 3.4 X 3.0 cm

TUMOR FOCALITY

Unifocal

MICROSCOPIC

HISTOLOGIC TYPE

Seminoma, classic type

MARGINS

Spermatic cord: Uninvolved by tumor

MICROSCOPIC TUMOR EXTENSION

Tumor invades tunica albuginea but not tunica vaginalis

LYMPHATIC/VASCULAR INVASION

Present

PATHOLOGIC STAGING

EXTENT OF INVASION

pT2. (Tumor limited to the testis and epididymis with vascular/lymphatic invasion)

REGIONAL LYMPH NODES

pNX. (Regional lymph nodes cannot be assessed)

DISTANT METASTASIS

pM0. (No distant metastasis)

SERUM TUMOR MARKERS

SX. (Serum marker studies not available or performed [Although LDH, HCG, and AFP values may be available, the 'S' designation in AJCC staging specifically refers to post-orchiectiony levels. These levels are currently not available])

PATHOLOGIC STAGE Summary

Final TNM: pT2NXM0

ICD-O-3
Seminoma NOS 9061/3
Site OSCE Testis NOS C62.9
@ Testicle NOS C62.9

9/21/04/13

[page 2 of 2]
2010 stage: I

- * The pathologic stage presumes no lymph node metastasis.
- ** The pathologic stage presumes no distant metastasis.

Attending Pathologist: [REDACTED]

CLINICAL INFORMATION

Right testicular mass

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Right testicle and cord

The specimen is received fresh labeled "right testicle and cord." It consists of a 46 gram, 5.9 x 3.6 x 3.1 cm testicle with attached 15.5 cm of spermatic cord. The specimen is inked. The spermatic cord is serially sectioned. No areas of suspicion are appreciated. Representative sections of the margin and additional random are sampled.

The tunica vaginalis is opened. It is not adherent to the white smooth tunica albuginea. The epididymis measures 5.5 x 1 x 0.5 cm.

The testicle is opened. There is a 4.9 x 3.4 x 3 cm lobulated mass that occupies the majority of the testicular parenchyma. Approximately 75% of the mass has a firm tan-white appearance. The remainder of the mass has a tan, markedly soft cut surface. Within these soft areas are multiple fibrous strands. A representative section of each area is submitted for frozen.

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Seminoma - additional sections pending to rule out additional germ cell elements" is rendered by [REDACTED]

The mass extends up to but not through the tunica albuginea. It extends up to but does not appear to involve the rete testis.

The remaining testicular parenchyma is pink and slightly lobulated. The seminiferous tubules do not string with ease.

The epididymis is sectioned. The majority of the cut surfaces are pink. There is a 1.2 x 0.8 x 0.5 cm area of orange discoloration in the head.

Representative sections are submitted in 14 cassettes labeled:

1. Frozen section residue
2. Spermatic cord margin
3. Tissue adjacent to spermatic cord margin
4. Additional random spermatic cord
- 5-6. Testicular mass in head of epididymis, includes entire head of epididymis
- 7-8. Mass and rete testis
- 9-14. Additional sections of mass (cassette 14 also includes area of uninvolved testicle parenchyma)

Gross dictation by: [REDACTED]

MICROSCOPIC

The microscopic appearance substantiates the diagnosis. Dictation transcribed [REDACTED]

COLLECTED:

SIGNED:

Lab and Collection

Source: NCI Genomic Data Commons file e9a05a5b-0207-4c62-bcab-efcafc0ef937 (TCGA-WZ-A7V5.E9930441-D85D-45B8-9410-31E4DB7BC693.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).